Somatic mutation profile of cancer-model specimen HCM-BROD-0420-C71-85R (3D Neurosphere, passage 10; aliquot HCM-BROD-0420-C71-85R-01D-A82H-36), derived from the recurrence tumor of HCMI case HCM-BROD-0420-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.3 years (17,653 days).
Specimen HCM-BROD-0420-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70d2c7fd-482a-4878-ba53-e762d95190ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0420-C71-10B (Blood Derived Normal), aliquot HCM-BROD-0420-C71-10B-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dd6241f-aa60-4e9a-a24c-9f9238fa0620

The open-access MAF lists 111 somatic variants for this specimen: 90 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 16, Frame Shift Del 8, Nonsense Mutation 6, RNA 2, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, Intron 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 142/308 reads (46%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 66/66 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD110181, CM033671, CM1513166, CM992427, COSV64288766, COSV64288772, COSV64297208, COSV64305848; called by muse, mutect2, varscan2
- ABCB1 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 172/552 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); catalogued as rs2235036; called by muse, mutect2, varscan2
- ABCG1 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 212/468 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV100494177; called by muse, mutect2, varscan2
- ACACA | c.2824A>G p.S942G | Missense Mutation (SNP) | VAF 252/537 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as rs376394653; called by muse, mutect2, varscan2
- AKR1B10 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 52/483 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100610162; called by muse, mutect2, varscan2
- CORO2B | c.435G>C p.W145C | Missense Mutation (SNP) | VAF 264/270 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958795; called by muse, mutect2, varscan2
- EXOC1L | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV101544650; called by muse, mutect2
- FAM153A | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs750905945, COSV62362244; called by muse, mutect2, varscan2
- HECW2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs778909020, COSV53657649; called by muse, mutect2, varscan2
- KCNT1 | c.1927G>A p.V643M (on ENST00000488444; = p.V662M on NM_020822.3) | Missense Mutation (SNP) | VAF 34/739 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs757867931, COSV53704687; called by muse, mutect2
- KIF26A | c.3914C>T p.P1305L | Missense Mutation (SNP) | VAF 393/872 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); catalogued as rs771670278, COSV59469211; called by muse, mutect2, varscan2
- MAGI2 | c.2839A>G p.T947A | Missense Mutation (SNP) | VAF 123/365 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs780222573; called by muse, mutect2, varscan2
- MUC12 | c.2576C>A p.T859N (on ENST00000379442; = p.T716N on NM_001164462.1) | Missense Mutation (SNP) | VAF 172/876 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs1321823487; called by mutect2, varscan2
- NF1 | c.4108C>T p.Q1370* | Nonsense Mutation (SNP) | VAF 158/293 reads (54%) | catalogued as rs868573462, CD1311340, CM114621, COSV62192664; called by muse, mutect2, varscan2
- NOS3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 345/1038 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1277224565, COSV52497537; called by muse, mutect2, varscan2
- NOVA2 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 29/1187 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs904775143, COSV54360062; called by muse, mutect2
- PBXIP1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 286/610 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs768024824; called by muse, varscan2
- PCDHB14 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 274/531 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1554289025; called by muse, mutect2, varscan2
- PLCG2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 263/556 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100842532, COSV63867739; called by muse, mutect2, varscan2
- PLEKHG4B | c.2982C>T p.D994= (on ENST00000283426; = p.D1350= on NM_052909.5) | Splice Region (SNP) | VAF 206/437 reads (47%) | catalogued as rs751935586; called by muse, mutect2
- POM121L12 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 338/1082 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV68692951, COSV68693360; called by muse, varscan2
- POM121L12 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 178/1227 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV101374987, COSV101375000; called by muse, varscan2
- PRDM9 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 235/618 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs375086019; called by muse, varscan2
- SLAMF9 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63636906; called by muse, mutect2
- SLC7A14 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 321/653 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs761358624, COSV51584914; called by muse, mutect2, varscan2
- TACC2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 321/321 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs757642911, COSV57751654; called by muse, mutect2, varscan2
- TDRD9 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs764661057; called by muse, mutect2, varscan2
- USH2A | c.5104G>A p.V1702M | Missense Mutation (SNP) | VAF 185/378 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs201799575, COSV56324658, COSV56376540; called by muse, mutect2, varscan2
- USP40 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 203/431 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs750860688; called by muse, mutect2, varscan2
- WDR87 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 252/786 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157851516; called by muse, varscan2
- ZNF831 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 342/660 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64040627; called by muse, varscan2
- AKAP6 | c.2647_2657del p.L883Gfs*11 | Frame Shift Del (DEL) | VAF 141/272 reads (52%) | called by mutect2, pindel, varscan2
- ATG9A | c.2433dup p.D812Rfs*10 | Frame Shift Ins (INS) | VAF 281/721 reads (39%) | called by mutect2, pindel, varscan2
- ATP11A | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C9 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CBFA2T2 | c.1793C>G p.A598G | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CDH8 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 218/382 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CHADL | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 334/667 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CRYBG1 | c.3103G>C p.E1035Q | Missense Mutation (SNP) | VAF 174/494 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, varscan2
- DIAPH2 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 71/73 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DIAPH2 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 73/76 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DLG4 | c.505+1G>A p.X169_splice (on ENST00000399506 / NM_001321075.3; = p.X212_splice on NM_001365.4) | Splice Site (SNP) | VAF 202/385 reads (52%) | called by muse, mutect2, varscan2
- FAM20C | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 72/612 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FOXD4L4 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 161/952 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FRMPD4 | c.934A>T p.S312C | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- GABBR2 | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 155/289 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSTM3 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GYS2 | c.491_495+26del p.X164_splice | Splice Site (DEL) | VAF 94/221 reads (43%) | called by mutect2, pindel, varscan2
- IBA57 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 265/567 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JCAD | c.1284T>G p.D428E | Missense Mutation (SNP) | VAF 269/272 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD4 | c.719T>C p.I240T | Missense Mutation (SNP) | VAF 128/244 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KPNB1 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRT33B | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 121/663 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- LBP | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, varscan2
- MAG | c.800_819del p.P267Hfs*114 | Frame Shift Del (DEL) | VAF 200/969 reads (21%) | called by mutect2, pindel, varscan2
- MAST4 | c.3892C>T p.P1298S (on ENST00000403625 / NM_001164664.2; = p.P1109S on NM_015183.3) | Missense Mutation (SNP) | VAF 76/469 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC12 | c.14806G>T p.E4936* (on ENST00000379442; = p.E4793* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 283/827 reads (34%) | called by muse, mutect2, varscan2
- MUC5B | c.8450G>C p.R2817T | Missense Mutation (SNP) | VAF 481/1025 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1R1P | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2C3 | c.911A>T p.H304L | Missense Mutation (SNP) | VAF 192/370 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- OR51E1 | c.551A>G p.H184R | Missense Mutation (SNP) | VAF 166/383 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAQR6 | c.743del p.G248Dfs*187 (on ENST00000292291 / NM_001272108.2; = p.G142Dfs*28 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 283/688 reads (41%) | called by mutect2, pindel, varscan2
- PCDH15 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PGBD4 | c.1639del p.Q547Nfs*58 | Frame Shift Del (DEL) | VAF 236/332 reads (71%) | called by mutect2, pindel, varscan2
- PLCZ1 | c.1343A>G p.K448R | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PLK1 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 236/480 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- POPDC3 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 128/218 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PRSS23 | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 238/513 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYHIN1 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QKI | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 138/141 reads (98%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RMDN2 | c.749G>T p.R250I (on ENST00000354545 / NM_001322212.2; = p.R428I on NM_144713.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SATB1 | c.2028G>C p.Q676H | Missense Mutation (SNP) | VAF 240/496 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDK2 | c.4373C>A p.A1458D | Missense Mutation (SNP) | VAF 247/502 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SH3TC1 | c.2622G>C p.K874N | Missense Mutation (SNP) | VAF 374/800 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SHISA7 | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 316/933 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SORL1 | c.966_967del p.S323Cfs*24 | Frame Shift Del (DEL) | VAF 69/419 reads (16%) | called by mutect2, pindel, varscan2
- SP4 | c.1442C>A p.S481* | Nonsense Mutation (SNP) | VAF 265/729 reads (36%) | called by muse, mutect2, varscan2
- TDO2 | c.747A>C p.E249D | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM272 | c.35_47del p.C12Sfs*21 | Frame Shift Del (DEL) | VAF 150/157 reads (96%) | called by mutect2, pindel, varscan2
- TPR | c.2908A>G p.T970A | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPTE | c.459T>A p.Y153* (on ENST00000618007 / NM_199261.4; = p.Y135* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2
- TTN | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TUBGCP6 | c.4591_4602del p.F1531_S1534del | In Frame Del (DEL) | VAF 199/490 reads (41%) | called by mutect2, pindel, varscan2
- WNT5A | c.703_704del p.D235Cfs*13 | Frame Shift Del (DEL) | VAF 170/472 reads (36%) | called by mutect2, pindel, varscan2
- ZDHHC2 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFP28 | c.2393G>A p.G798E | Missense Mutation (SNP) | VAF 164/450 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZFR2 | c.2376C>G p.I792M | Missense Mutation (SNP) | VAF 305/919 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ZNF263 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 251/525 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF473 | c.2395_2398del p.A799Ifs*2 | Frame Shift Del (DEL) | VAF 182/650 reads (28%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.1032C>T p.G344= | Silent (SNP) | VAF 147/543 reads (27%) | catalogued as rs142122012, COSV62145397; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- DRD1 | c.711C>T p.H237= | Silent (SNP) | VAF 217/471 reads (46%) | catalogued as rs777655360, COSV67104736; called by muse, mutect2, varscan2
- IL2RB | c.435C>T p.T145= | Silent (SNP) | VAF 21/552 reads (4%) | called by muse, mutect2
- KCNT2 | c.1704G>A p.Q568= | Silent (SNP) | VAF 117/262 reads (45%) | catalogued as COSV54079473; called by muse, mutect2, varscan2
- MASTL | c.1356C>T p.S452= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- MUC16 | c.22926C>G p.T7642= | Silent (SNP) | VAF 75/820 reads (9%) | called by muse, mutect2
- NOTCH4 | c.1174T>C p.L392= | Silent (SNP) | VAF 22/558 reads (4%) | called by muse, mutect2
- OR52K2 | c.225T>A p.L75= | Silent (SNP) | VAF 250/530 reads (47%) | called by muse, mutect2, varscan2
- PCK1 | c.1554G>A p.R518= | Silent (SNP) | VAF 251/513 reads (49%) | catalogued as COSV100100516, COSV60126658; called by muse, mutect2, varscan2
- POR | c.1896T>C p.C632= | Silent (SNP) | VAF 186/581 reads (32%) | catalogued as rs1314816016; called by muse, mutect2, varscan2
- RBM47 | c.1557T>C p.T519= (on ENST00000295971 / NM_001098634.2; = p.T450= on NM_019027.4) | Silent (SNP) | VAF 147/317 reads (46%) | catalogued as rs1383042491; called by muse, mutect2, varscan2
- RPAP3 | c.36A>G p.L12= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs768520605; called by muse, mutect2, varscan2
- SLC1A7 | c.837G>A p.K279= | Silent (SNP) | VAF 94/474 reads (20%) | called by muse, mutect2, varscan2
- TMEM132C | c.2070G>A p.K690= | Silent (SNP) | VAF 24/472 reads (5%) | called by muse, mutect2
- TUBGCP3 | c.2112T>C p.C704= | Silent (SNP) | VAF 141/145 reads (97%) | called by muse, mutect2, varscan2
- USP9Y | c.6483A>G p.T2161= | Silent (SNP) | VAF 100/100 reads (100%) | catalogued as rs1392257229; called by muse, mutect2, varscan2
- ATOX1 | c.7-522C>T | Intron (SNP) | VAF 198/436 reads (45%) | called by muse, mutect2, varscan2
- C5orf60 | n.2364G>A | RNA (SNP) | VAF 295/568 reads (52%) | catalogued as rs776621362, COSV71508536; called by muse, mutect2, varscan2
- CCDC90B | c.-147G>A | 5'UTR (SNP) | VAF 115/601 reads (19%) | called by muse, mutect2, varscan2
- COLGALT2 | c.*1903T>A | 3'UTR (SNP) | VAF 44/320 reads (14%) | called by muse, mutect2, varscan2
- FAM169B | n.519G>A | RNA (SNP) | VAF 79/276 reads (29%) | catalogued as rs779102239; called by muse, mutect2, varscan2
